Somatic mutation profile of tumor specimen MMRF_2531_1_PB_CD138pos (aliquot MMRF_2531_1_PB_CD138pos_T2_KHS5U_K15150) from MMRF case MMRF_2531, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.5 years (25,765 days).
Specimen MMRF_2531_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12fab69-ef2d-435b-af53-d25ae80f8c1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2531_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2531_1_PB_CD3pos_C5_KHS5U_K15148; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca3d8983-d9c8-40c8-9d46-b1fcc2928639

The open-access MAF lists 117 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 44, Missense Mutation 35, Intron 12, Silent 12, 5'UTR 6, Nonsense Mutation 3, Splice Site 2, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs1189976702; called by muse, mutect2, varscan2
- AKAP17A | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1204041488; called by muse, mutect2, varscan2
- AKR1B10 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.643); catalogued as rs769711685; called by muse, mutect2, varscan2
- BIRC3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325194761, COSV54819909; called by muse, varscan2
- CASP4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs147548594, COSV67744743; called by muse, mutect2, varscan2
- CIC | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs200040001; called by muse, mutect2, varscan2
- DCHS1 | c.4598G>A p.R1533H | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as rs1158050214; called by muse, varscan2
- GNRHR | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56934608; called by muse, mutect2, varscan2
- IGHV2-70 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs144976346; called by muse, varscan2
- IGLV3-1 | c.203A>C p.Q68P | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs373323725; called by muse, mutect2, varscan2
- INTS1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs1343068610; called by muse, mutect2, varscan2
- LRRC72 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1357337462; called by muse, mutect2, varscan2
- LRRC8B | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV58376910; called by muse, mutect2, varscan2
- OLA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV52974073; called by muse, varscan2
- RHOBTB3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as rs768905935, COSV66102659; called by muse, mutect2, varscan2
- ROBO4 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs991169562, COSV60628060; called by muse, mutect2, varscan2
- TRRAP | c.9511C>T p.R3171W (on ENST00000359863 / NM_001244580.1; = p.R3142W on NM_003496.3) | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778465879, COSV62838500; called by muse, mutect2, varscan2
- ACE | c.3279C>T p.L1093= | Splice Region (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- BIRC3 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CENPO | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF16 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.31); called by muse, mutect2
- DPCD | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP1 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- FIGNL2 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- G6PC2 | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- GSK3A | c.745A>G p.N249D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- KIAA1217 | c.4045G>C p.V1349L | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- KLHL36 | c.1631G>A p.W544* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- LTB | c.163-2A>C p.X55_splice | Splice Site (SNP) | VAF 156/380 reads (41%) | called by muse, varscan2
- METTL8 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NLRP1 | c.366T>G p.H122Q | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, varscan2
- PEX6 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2
- PIPOX | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLEKHA5 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PLEKHG4B | c.2947G>A p.D983N (on ENST00000283426; = p.D1339N on NM_052909.5) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRDM1 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A1 | c.370+1G>A p.X124_splice | Splice Site (SNP) | VAF 30/43 reads (70%) | called by muse, mutect2, varscan2
- TKTL2 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRIM41 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBE2J1 | c.27T>G p.S9R | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- VWA5B1 | c.2341A>T p.T781S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP10B | c.1602G>A p.V534= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1338032971; called by muse, mutect2, varscan2
- BIRC3 | c.750G>C p.L250= | Silent (SNP) | VAF 76/190 reads (40%) | catalogued as rs924808678, COSV99679629; called by muse, varscan2
- FNDC3B | c.2019A>G p.Q673= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as rs775169168; called by muse, mutect2, varscan2
- KIF26A | c.1038G>A p.L346= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs749811229; called by muse, mutect2, varscan2
- LEPROTL1 | c.336T>G p.T112= | Silent (SNP) | VAF 128/195 reads (66%) | called by muse, mutect2, varscan2
- MMP1 | c.219G>A p.L73= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV59509381; called by muse, mutect2, varscan2
- MMP1 | c.132G>A p.L44= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, varscan2
- POU6F2 | c.1047G>A p.L349= | Silent (SNP) | VAF 66/163 reads (40%) | catalogued as rs1422111351, COSV101302853; called by muse, varscan2
- RTL5 | c.372C>T p.P124= | Silent (SNP) | VAF 42/48 reads (88%) | called by muse, mutect2, varscan2
- SOX8 | c.411C>T p.G137= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5541G>A p.Q1847= | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as rs772532941; called by muse, mutect2, varscan2
- UBE2I | c.405G>A p.T135= | Silent (SNP) | VAF 98/257 reads (38%) | catalogued as rs542048272; called by muse, mutect2, varscan2
- ADCY2 | c.*2226G>A | 3'UTR (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- ANKRD34B | c.*780C>A | 3'UTR (SNP) | VAF 27/72 reads (38%) | catalogued as rs886354044; called by muse, mutect2, varscan2
- ARHGAP31 | c.*1739C>T | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- BEND4 | c.*3688G>A | 3'UTR (SNP) | VAF 45/98 reads (46%) | catalogued as rs1032243188; called by muse, mutect2, varscan2
- BIRC3 | c.-167G>A | 5'UTR (SNP) | VAF 24/79 reads (30%) | catalogued as rs1322913919; called by muse, mutect2, varscan2
- BIRC3 | c.-75G>C | 5'UTR (SNP) | VAF 68/160 reads (43%) | called by muse, varscan2
- CDH8 | c.-44dup | 5'UTR (INS) | VAF 30/73 reads (41%) | catalogued as rs746335090; called by mutect2, varscan2
- CENPB | c.*307C>T | 3'UTR (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- CREB5 | c.*6002C>G | 3'UTR (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- CYHR1 | c.247-2461G>T | Intron (SNP) | VAF 60/133 reads (45%) | called by muse, varscan2
- DIP2C | c.*3115T>G | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- EGLN1 | c.*2000C>T | 3'UTR (SNP) | VAF 53/90 reads (59%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*5775C>T | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- EIF5 | c.*169C>T | 3'UTR (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- ELK4 | c.*5796A>G | 3'UTR (SNP) | VAF 56/88 reads (64%) | called by muse, varscan2
- FAM217B | c.*415C>T | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- FBN2 | c.-577G>T | 5'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- FZD4 | c.*3864G>A | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- GABRA4 | c.*219C>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- GABRG2 | chr5:162067655 G>T | 5'Flank (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- GBP1P1 | n.1580T>C | RNA (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- GCSAML | c.*2636T>C | 3'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- GDNF | c.*2908C>T | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- GPR84 | c.*10C>T | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, varscan2
- GREM2 | c.*358G>A | 3'UTR (SNP) | VAF 46/194 reads (24%) | called by muse, mutect2, varscan2
- KCNN3 | c.933+9192G>A | Intron (SNP) | VAF 68/187 reads (36%) | called by muse, mutect2
- KIAA1109 | c.*301T>G | 3'UTR (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- KLF4 | c.6-31C>T | Intron (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- LIMD1 | c.*174C>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- LMO7 | c.1307+41C>T | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, varscan2
- LNPEP | c.*1271G>T | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- LY6K | c.*450C>T | 3'UTR (SNP) | VAF 33/94 reads (35%) | catalogued as rs782321006; called by muse, mutect2, varscan2
- METTL2A | c.*3891G>A | 3'UTR (SNP) | VAF 65/146 reads (45%) | called by muse, mutect2, varscan2
- MIEF2 | c.*971G>T | 3'UTR (SNP) | VAF 23/35 reads (66%) | catalogued as COSV59902238; called by muse, mutect2, varscan2
- MSL3 | c.102+300G>A | Intron (SNP) | VAF 27/30 reads (90%) | catalogued as COSV100384834; called by muse, mutect2, varscan2
- NPAT | c.*1384C>G | 3'UTR (SNP) | VAF 41/65 reads (63%) | called by muse, mutect2, varscan2
- OTOF | c.*349C>T | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- PAX6 | c.142-182C>T | Intron (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- PHF6 | c.968+1086A>C | Intron (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- PRND | c.*2951C>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, varscan2
- RMND1 | c.*250G>A | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- RNF149 | c.*927C>G | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- SASH1 | c.*280C>T | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SCP2 | c.*653A>G | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- SDC2 | c.*2074G>A | 3'UTR (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- SH3TC1 | c.172+531G>A | Intron (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SHQ1 | c.*167G>C | 3'UTR (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- SLC13A1 | c.99+9370T>G | Intron (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- SLC30A9 | c.*1125dup | 3'UTR (INS) | VAF 22/46 reads (48%) | catalogued as rs1337719119; called by mutect2, varscan2
- SLC5A2 | c.1022-88G>A | Intron (SNP) | VAF 45/87 reads (52%) | catalogued as rs537526690; called by muse, mutect2, varscan2
- SLCO1A2 | c.*2928G>A | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- SMIM4 | c.-116G>C | 5'UTR (SNP) | VAF 65/154 reads (42%) | catalogued as rs1032427066; called by muse, mutect2, varscan2
- SNX13 | c.2626+646A>T | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*2707G>A | 3'UTR (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- STRAP | c.-284G>A | 5'UTR (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- STX7 | c.*1754T>C | 3'UTR (SNP) | VAF 29/73 reads (40%) | called by muse, varscan2
- TAF5L | c.*282C>T | 3'UTR (SNP) | VAF 124/382 reads (32%) | catalogued as rs987730544; called by muse, mutect2
- TENT5A | c.*1236C>T | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3360T>G | 3'UTR (SNP) | VAF 114/248 reads (46%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+167G>A | Intron (SNP) | VAF 36/98 reads (37%) | catalogued as rs985996018; called by muse, mutect2, varscan2
- TOMM70 | c.*1387C>T | 3'UTR (SNP) | VAF 43/100 reads (43%) | catalogued as rs758849185; called by muse, mutect2, varscan2
- UNC5A | c.*14C>T | 3'UTR (SNP) | VAF 50/146 reads (34%) | catalogued as rs373776635, COSV99458601; called by muse, mutect2, varscan2
- UTP25 | c.*518C>T | 3'UTR (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- ZIC1 | c.*1573C>T | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
